FM case AD1895 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mucoepidermoid Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/51bd3fa9-8d65-4380-a199-2411608d9b67

Female, 76.4 years: Mucoepidermoid carcinoma (ICD-O-3 8430/3) of the major salivary gland; specimen biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 70% (pathologist estimate recorded by GDC). Sample type: Tumor.
